Somatic mutation profile of tumor specimen MP2PRT-PAUVJH-TMP1-A (aliquot MP2PRT-PAUVJH-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUVJH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,453 days).
Specimen MP2PRT-PAUVJH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f10d1df0-9520-418a-8eea-40de5716a565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVJH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVJH-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eb16c31-3d1b-46ef-9cdc-e2a9377366e9

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 176/405 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs766561912, COSV55210925; called by muse, mutect2
- CDK12 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 187/405 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70999629; called by muse, mutect2, varscan2
- COL24A1 | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753389009; called by muse, mutect2, varscan2
- HOXB1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 248/550 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53316599; called by muse, mutect2
- SLC27A6 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs373236456; called by muse, mutect2, varscan2
- SPOCK1 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs569345414, COSV56435804; called by muse, mutect2, varscan2
- ADCY3 | c.980_981insGGCC p.F328Afs*26 | Frame Shift Ins (INS) | VAF 105/319 reads (33%) | called by mutect2, pindel, varscan2
- PTPN5 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DNHD1 | c.2016C>T p.F672= | Silent (SNP) | VAF 200/420 reads (48%) | called by muse, mutect2
- HSPA12A | c.339C>T p.S113= | Silent (SNP) | VAF 195/410 reads (48%) | called by muse, mutect2, varscan2
- PIEZO2 | c.786G>A p.T262= | Silent (SNP) | VAF 172/384 reads (45%) | catalogued as rs1320885573; called by muse, mutect2, varscan2
- SCARA3 | c.849G>C p.L283= | Silent (SNP) | VAF 211/454 reads (46%) | called by muse, mutect2, varscan2
- AL132655.7 | n.47G>A | RNA (SNP) | VAF 224/476 reads (47%) | called by muse, mutect2, varscan2
